Somatic mutation profile of tumor specimen 0DK5HK from CCDI case PBBXUY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic infantile astrocytoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.9 years (344 days).
Specimen 0DK5HK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d37f4385-eedd-4314-8fea-4eb1585310c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK5HQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/575ea19f-b47e-4905-b1b1-9de010d40a1e

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/409 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1920G>T p.V640= (on ENST00000288602 / NM_001374244.1; = p.V600= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 69/413 reads (17%) | catalogued as COSV56107175, COSV56109586; called by muse, mutect2, varscan2
- IRF6 | c.1209C>T p.Y403= | Silent (SNP) | VAF 61/365 reads (17%) | catalogued as rs774866638, CM067421, COSV54214427, COSV54214734; called by muse, mutect2, varscan2
- PATL2 | c.1419G>A p.S473= | Silent (SNP) | VAF 39/283 reads (14%) | catalogued as rs1024719184; called by muse, mutect2, varscan2
